Somatic mutation profile of tumor specimen MP2PRT-PAPDGD-TMP1-A (aliquot MP2PRT-PAPDGD-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPDGD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.1 years (413 days).
Specimen MP2PRT-PAPDGD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbd1d6be-5a48-44ec-978d-c495f090e90f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPDGD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPDGD-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/615da241-297b-4741-a618-7abbe87ca886

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 142/391 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DZIP1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 134/406 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs749877973; called by muse, mutect2, varscan2
- HS3ST6 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 94/677 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1264604709, COSV53534268; called by muse, mutect2, varscan2
- LRRC56 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 33/792 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs942621893; called by muse, mutect2
- NACAD | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 89/608 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV71989496; called by mutect2, varscan2
- PCDHGB1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 263/710 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as rs1440870321; called by muse, mutect2, varscan2
- NRAS | c.33A>C p.A11= | Silent (SNP) | VAF 140/387 reads (36%) | called by muse, mutect2, varscan2
- TPO | c.482+2460G>A | Intron (SNP) | VAF 104/325 reads (32%) | catalogued as rs556536030, COSV100220060; called by muse, mutect2, varscan2
